Somatic mutation profile of tumor specimen MMRF_2505_1_BM_CD138pos (aliquot MMRF_2505_1_BM_CD138pos_T1_KHS5U_L11634) from MMRF case MMRF_2505, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.6 years (25,054 days).
Specimen MMRF_2505_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3d49e8f-3210-4c4c-9189-de457e37fa16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2505_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2505_1_PB_Whole_C3_KHS5U_L11635; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a004a8ab-a202-4481-ac7c-aa52e054cc2f

The open-access MAF lists 98 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 25, Intron 15, Silent 9, Nonsense Mutation 4, 3'Flank 4, 5'Flank 3, Splice Site 3, RNA 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 37/98 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIM1 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 85/193 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.48); PolyPhen benign (0.062); catalogued as COSV65164988, COSV65166078, COSV65166386; called by muse, mutect2, varscan2
- C3AR1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 113/158 reads (72%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs56297048, COSV50820555; called by muse, mutect2, varscan2
- CLCNKA | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as rs774294391, COSV104403449; called by muse, mutect2, varscan2
- COL11A2 | c.4882G>C p.E1628Q (on ENST00000341947 / NM_080680.3; = p.E1521Q on NM_080679.2) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV59503419; called by muse, mutect2, varscan2
- DDX19A | c.929A>G p.Y310C | Missense Mutation (SNP) | VAF 91/398 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs773246101; called by muse, mutect2, varscan2
- DPY19L2 | c.610T>C p.C204R | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1380645268, COSV60543307; called by muse, mutect2
- IGKV2-24 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 154/296 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs1316764884; called by muse, mutect2, varscan2
- IGLV3-1 | c.313T>G p.Y105D | Missense Mutation (SNP) | VAF 99/290 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs574479963; called by muse, mutect2
- JAG2 | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 50/52 reads (96%) | SIFT tolerated (0.62); PolyPhen benign (0.075); catalogued as rs587730186, COSV104405213; called by muse, mutect2, varscan2
- JMJD4 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs757199014, COSV59917670; called by muse, mutect2, varscan2
- MUC2 | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555122993; called by muse, mutect2, varscan2
- PDZD7 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs963259509; called by muse, mutect2, varscan2
- RBMS3 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56176214; called by muse, mutect2, varscan2
- SCARB1 | c.635A>G p.N212S | Missense Mutation (SNP) | VAF 186/351 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211982437; called by muse, mutect2, varscan2
- SETD2 | c.4920G>A p.W1640* | Nonsense Mutation (SNP) | VAF 106/204 reads (52%) | catalogued as COSV57439612, COSV57440632; called by muse, mutect2, varscan2
- VPS18 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 147/322 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs537691205; called by muse, mutect2, varscan2
- ZC3H7B | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 77/141 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs1433016424, COSV60960795; called by muse, mutect2, varscan2
- ADGRL4 | c.1222C>A p.H408N | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.262); called by muse, mutect2
- CFAP47 | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 60/128 reads (47%) | called by muse, varscan2
- CFAP47 | c.885+1G>A p.X295_splice | Splice Site (SNP) | VAF 28/52 reads (54%) | called by muse, varscan2
- DENND2A | c.2663A>T p.H888L | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- FASTKD3 | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 174/364 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- GFI1 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRIK2 | c.1952A>T p.Y651F | Missense Mutation (SNP) | VAF 111/229 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GZMA | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 288/572 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IGHV2-70 | c.137_158delinsCTCACTCAGTACTGATGCAAC p.F46Sfs*10 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | called by muse*, pindel
- KREMEN2 | c.361+1G>A p.X121_splice | Splice Site (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- LRRC17 | c.67C>A p.P23T | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- LTB | c.208+2T>C p.X70_splice | Splice Site (SNP) | VAF 134/335 reads (40%) | called by muse, mutect2, varscan2
- MBTD1 | c.314A>T p.K105I | Missense Mutation (SNP) | VAF 69/150 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- PRDM7 | c.1275G>A p.W425* | Nonsense Mutation (SNP) | VAF 107/399 reads (27%) | called by muse, mutect2, varscan2
- R3HDM1 | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2
- RAD51AP2 | c.1949G>A p.R650K | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- RAPGEF2 | c.11A>C p.Y4S | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC46A2 | c.1394C>A p.P465Q | Missense Mutation (SNP) | VAF 187/409 reads (46%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC7A8 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TMEM131L | c.39C>A p.C13* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- TMEM39A | c.1202T>A p.V401E | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- ZNF729 | c.921T>G p.F307L | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANHX | c.246G>A p.L82= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- BANP | c.1401C>T p.G467= (on ENST00000286122; = p.G417= on NM_017869.4) | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as rs563007703; called by muse, mutect2
- DUSP2 | c.253C>T p.L85= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs551318349, COSV56620804; called by muse, mutect2, varscan2
- IGLV3-1 | c.192G>A p.L64= | Silent (SNP) | VAF 84/144 reads (58%) | catalogued as rs538500170; called by muse, varscan2
- INTS10 | c.1716T>C p.F572= | Silent (SNP) | VAF 120/239 reads (50%) | called by muse, mutect2, varscan2
- NLRP9 | c.2070G>C p.L690= | Silent (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- POMC | c.208C>T p.L70= | Silent (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2, varscan2
- SBF2 | c.2632C>T p.L878= | Silent (SNP) | VAF 24/43 reads (56%) | called by muse, mutect2, varscan2
- UNC80 | c.9330G>A p.V3110= | Silent (SNP) | VAF 37/84 reads (44%) | catalogued as COSV55901119; called by muse, mutect2, varscan2
- ACVR2A | c.*3099A>T | 3'UTR (SNP) | VAF 4/30 reads (13%) | catalogued as rs1288191257, COSV51575648; called by muse, varscan2
- AMER3 | c.*1687G>A | 3'UTR (SNP) | VAF 30/61 reads (49%) | catalogued as rs1279027884; called by muse, mutect2, varscan2
- ANO5 | c.*975A>C | 3'UTR (SNP) | VAF 53/111 reads (48%) | catalogued as rs765993463; called by muse, mutect2, varscan2
- ANXA2 | c.-116-2709T>C | Intron (SNP) | VAF 75/160 reads (47%) | called by muse, mutect2, varscan2
- ARID2 | chr12:45727465 A>G | 5'Flank (SNP) | VAF 69/139 reads (50%) | called by muse, mutect2, varscan2
- ARIH1 | c.*625T>A | 3'UTR (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- BMP6 | c.*1267A>T | 3'UTR (SNP) | VAF 34/136 reads (25%) | called by muse, mutect2, varscan2
- BRD9 | c.967-178G>A | Intron (SNP) | VAF 14/25 reads (56%) | catalogued as rs1030654494; called by muse, mutect2, varscan2
- C11orf96 | chr11:43943701 T>C | 3'Flank (SNP) | VAF 77/173 reads (45%) | called by muse, mutect2, varscan2
- CATIP | c.320-99G>A | Intron (SNP) | VAF 39/76 reads (51%) | catalogued as rs146083370; called by muse, mutect2, varscan2
- CCSER1 | c.*40G>A | 3'UTR (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- CNTN5 | c.2730+893T>C | Intron (SNP) | VAF 43/79 reads (54%) | called by muse, mutect2, varscan2
- CXorf66 | c.*47C>T | 3'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- FGFR4 | c.436+49A>G | Intron (SNP) | VAF 182/391 reads (47%) | catalogued as rs888774380; called by muse, mutect2, varscan2
- GART | c.598-58A>T | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- GJA3 | c.*1516T>A | 3'UTR (SNP) | VAF 49/55 reads (89%) | called by muse, mutect2, varscan2
- GPR158 | c.*371G>A | 3'UTR (SNP) | VAF 22/142 reads (15%) | called by muse, mutect2, varscan2
- GRIP2 | c.782-76C>T | Intron (SNP) | VAF 68/154 reads (44%) | called by muse, mutect2, varscan2
- GULP1 | c.844-2753T>C | Intron (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- KIF2A | c.64+1927T>G | Intron (SNP) | VAF 29/46 reads (63%) | called by muse, mutect2, varscan2
- LINC00636 | n.471G>A | RNA (SNP) | VAF 228/388 reads (59%) | called by muse, mutect2, varscan2
- MAGOHB | c.*5T>G | 3'UTR (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- MEF2C | chr5:88718291 T>C | 3'Flank (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- MFAP3L | c.298+411A>G | Intron (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- MMADHC | c.*73A>C | 3'UTR (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2
- MYOT | c.-15A>T | 5'UTR (SNP) | VAF 103/202 reads (51%) | called by muse, mutect2, varscan2
- NACC2 | c.*1851C>T | 3'UTR (SNP) | VAF 56/112 reads (50%) | catalogued as rs775850647; called by muse, mutect2, varscan2
- NCAPH2 | c.862-86T>C | Intron (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- NEGR1 | c.*3612C>T | 3'UTR (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- NLGN1 | c.*2410A>C | 3'UTR (SNP) | VAF 83/136 reads (61%) | called by muse, mutect2, varscan2
- NLRP1 | c.3520+455T>G | Intron (SNP) | VAF 66/150 reads (44%) | called by muse, mutect2, varscan2
- NRXN1 | c.832+1988A>G | Intron (SNP) | VAF 171/402 reads (43%) | called by muse, mutect2, varscan2
- POLR3E | c.*851C>T | 3'UTR (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2
- PPIAP15 | chr3:109476735 A>C | 5'Flank (SNP) | VAF 52/87 reads (60%) | called by muse, mutect2, varscan2
- PRDM9 | c.*210G>A | 3'UTR (SNP) | VAF 23/77 reads (30%) | called by muse, mutect2, varscan2
- RHD | chr1:25272397 C>A | 5'Flank (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- SLITRK2 | chrX:145829428 A>C | 3'Flank (SNP) | VAF 36/37 reads (97%) | called by muse, mutect2, varscan2
- SORT1 | c.*2838G>A | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.*372C>A | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- TECRL | chr4:64276018 T>G | 3'Flank (SNP) | VAF 52/94 reads (55%) | called by muse, mutect2, varscan2
- TMEM98 | c.*399T>G | 3'UTR (SNP) | VAF 73/136 reads (54%) | called by muse, mutect2
- TUSC1 | c.*1247A>G | 3'UTR (SNP) | VAF 15/101 reads (15%) | called by muse, varscan2
- UGT3A2 | c.*292A>G | 3'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- USP13 | c.*1898T>G | 3'UTR (SNP) | VAF 14/126 reads (11%) | called by mutect2, varscan2
- WDR76 | c.60+11G>A | Intron (SNP) | VAF 60/207 reads (29%) | called by muse, mutect2, varscan2
- XKR4 | c.806+58259G>T | Intron (SNP) | VAF 107/272 reads (39%) | called by muse, mutect2, varscan2
- YTHDC1 | c.*165G>A | 3'UTR (SNP) | VAF 82/169 reads (49%) | called by muse, mutect2, varscan2
- ZC3H12C | c.*5705G>T | 3'UTR (SNP) | VAF 49/109 reads (45%) | called by muse, mutect2, varscan2
- ZNF345 | c.*535dup | 3'UTR (INS) | VAF 13/27 reads (48%) | catalogued as rs1228808988; called by mutect2, varscan2
